Surgical pathology report (de-identified scan), TCGA case TCGA-30-1869, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1869-01A (Primary Tumor).

[page 1 of 4]
Accession Number: [REDACTED] Report Status: Final
Type: Surgical Pathology
Pathology Report: [REDACTED] OMENTUM BIOPSY
Accessioned On: [REDACTED]

TCGA-30-1869

DIAGNOSIS:

SPECIMEN LABELED "OMENTAL BIOPSY" (including FSA):
METASTATIC PAPILLARY SEROUS CARCINOMA present in fibroadipose tissue.

SPECIMEN LABELED "RECTUS MUSCLE":
The entire specimen is submitted for research.

SPECIMEN LABELED "RIGHT ADNEXA":
PAPILLARY SEROUS CARCINOMA of the ovary, grade 3 (of 3).
Tumor is present on the surface of the ovary.
Tumor is present in the lumen and on the serosa of the fallopian tube.

SPECIMEN LABELED "LEFT ADNEXA":
PAPILLARY SEROUS CARCINOMA of the ovary, grade 3 (of 3).
Tumor is present on the surface of the ovary.
Fallopian tube not identified.
METASTIC PAPILLARY SEROUS CARCINOMA present in one (1) lymph node.

SPECIMEN LABELED "UTERUS AND CERVIX"
METASTATIC PAPILLARY SEROUS CARCINOMA.
Tumor involves the serosa, myometrium and cervical stroma.
Tumor is present in lymphatics of the cervix and myometrium.
Proliferative endometrium with endometrial polyp.
Leiomyomata (1.5 to 3.0 cm).

SPECIMEN LABELED "LEFT EXTERNAL ILIAC NODE":
METASTATIC PAPILLARY SEROUS CARCINOMA present in one (1) lymph node.

SPECIMEN LABELED "SIGMOID COLON":
METASTATIC PAPILLARY SEROUS CARCINOMA to the colonic serosa with
extension into the muscularis propria and present in the pericolonic
adipose tissue at the resection margins.

SPECIMEN LABELED "TUMOR ADJACENT TO RIGHT URETER":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "TUMOR AT SURFACE OF BLADDER":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "OMENTUM":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "SPLEEN":
METASTATIC PAPILLARY SEROUS CARCINOMA present in the hilum of the spleen
with extension into splenic parenchyma and the perisplenic soft tissue.

SPECIMEN LABELED "TUMOR FROM MESENTERY TRANSVERSE COLON":
METASTATIC PAPILLARY SEROUS CARCINOMA.
One (1) lymph node with no tumor present.

SPECIMEN LABELED "DIAPHRAGMATIC TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "SIGMOID COLON":
METASTATIC PAPILLARY SEROUS CARCINOMA present in the pericolonic adipose
tissue and focally extending to a resection margin.

SPECIMEN LABELED "DISTAL AND PROXIMAL ENDS OF ANASTOMOSIS":
Segments of colon with no tumor present.

[page 2 of 4]
CLINICAL DATA.

History: [REDACTED] with pelvic/omental mass, increase CA 125.
Clinical Diagnosis: Ovarian cancer

TISSUE SUBMITTED: 1. Omental biopsy (FS)*

2. Rectus muscle (given to pathologist)
3. Right adnexa
4. Left adnexa
5. Uterus & cervix
6. Left external iliac node
7. Sigmoid colon
8. Tumor adjacent to right ureter
9. Tumor at surface of bladder
10. Omentum
11. Spleen
12. Tumor from mesentery transverse colon
13. Diaphragmatic tumor
14. Sigmoid colon
15. Distal and proximal ends of anastomosis

O.R. CONSULTATION:

SPECIMEN DESIGNATED "OMENTUM":

Papillary serous carcinoma.

GROSS DESCRIPTION:

The specimen is received fresh in fifteen parts, each labeled with the patient's name and unit number.

Part one, "omental biopsy", and consists of a single fragment of omentum (8.2 x 2.9 x 1.7 cm) which contains multiple nodules of white/tan fibrotic tissue. A representative section is submitted for frozen section A. Representative sections are submitted for histologic evaluation.

Micro sections:

Micro 1: frozen section A remnant, [REDACTED]

Micro 2-3: representative fragments, 4 frags, [REDACTED]

Part two, "rectus muscle", consists of a single fragment of muscle (1.2 x 0.8 x 0.3 cm) which is grossly unremarkable and entirely submitted to [REDACTED]

Part three, "right adnexa", a single knotted brown/tan mass (5.5 x 5 x 2 cm), with attached fallopian tube (7 cm in length by 1 cm in greatest diameter). The mass is fragmented and granular with a small focus of smooth ovarian surface. The fallopian tube is grossly uninvolved by the tumor. There is a paratubal cyst filled with a serous fluid (1 cm). Scant identifiable residual ovary is present and the majority is diffusely replaced by tumor. Representative sections are submitted for histologic evaluation.

Micro 4-8: representative sections of ovary, multiple frags, [REDACTED]

Micro 9: fallopian tube, 4 frags, [REDACTED]

Part four, "left adnexa", consists of a tan/brown/blue matted mass (7 x 5.5 x 4 cm) which is extensively fragmented. No identifiable ovary is present nor fallopian tube. The mass consists of various of white/tan firm nodules, necrosis and hemorrhage. A 4.5 cm unilocular smooth walled cyst is identified within the mass. The tumor is grossly present at all margins. Representative sections are submitted for histologic evaluation.

Micro 10-14: 5 frags, [REDACTED]

Part five, "uterus with cervix", consists of a 105 gm hysterectomy specimen including a uterus (6.5 x 6 x 5 cm), and exocervix (2.5 x 2 cm) with a slit-like os (2 cm). The serosal surface is studded with multiple nodules of brown/tan firm tissue and areas of necrosis. An anterior and posterior endometrium cannot be identified. The endocervical canal (2 cm in length) is covered by a tan herringbone mucosa. The endometrial cavity (1 cm from cornu to cornu and 3 cm in length) has a tan/pink hemorrhagic endometrium (0.3 cm in maximum thickness). The myometrium (2.5 cm in maximum thickness) contains multiple leiomyomata (1.5 cm up to 3 cm). The serosal surface is completely

CGA-30-1869

[page 3 of 4]
involved by tumor (up to 1 cm in maximum thickness). Representative sections are submitted for histologic evaluation.

Micro 15-16: cervix, 2 frags,
Micro 17: LUS, 1 frag,
Micro 18: endometrium, 2 frags,
Micro 19-20: leiomyomas, 2 frags,
Micro 21-22: serosa, 2 frags,

TCGA-30-1869

Part six, "left external iliac nodes", consists of a single fragment of fibroadipose tissue (3 x 1.5 x 1 cm) which contains a single lymph node. The entire lymph node is submitted for histologic evaluation.

Micro 23: 1 lymph node, 2 frags,

Part seven, "sigmoid colon", is a single segment of colon (33 cm in length by 3 cm in diameter) with an opened resection margin (3 cm in diameter) and opposing staple resection margin (2.5 cm in length). The serosal surface is diffusely studded with white/tan hemorrhagic tumor nodules (up to 5 cm in greatest dimension). The tumor is grossly present in the pericolonc adipose tissue and either margin. The colonic mucosa is smooth, glistening with no direct involvement by the serosally [] tumor. The colonic resection margins are unremarkable. Representative sections are submitted for histologic evaluation.

Micro 24: opened resection margin, 3 frags,
Micro 25: pericolonc adipose tissue present at the opened resection margin, multiple frags,
Micro 26: staple resection margin en face, 2 frags,
Micro 27: pericolonc adipose tissue, present at staple resection margin, 2 frags,
Micro 28-30: fibrous tumor in relation to overlying mucosa, 4 frags

Part eight, "tumor adjacent to right ureter", consists of multiple fragments of firm, yellow/tan soft tissue (5 x 4 x 1 cm) which are grossly consistent with tumor. No identifiable ureter is present. Representative sections are submitted for histologic evaluation.

Micro 31: 3 frags,

Part nine, "tumor at surface of bladder", consists of multiple fragments of tan/yellow soft tissue (4 x 4 x 0.5 cm in aggregate) which are grossly consistent with tumor. No identifiable bladder mucosa is present. Representative sections are submitted for histologic evaluation.

Micro 32: multiple frags,

Part ten, "omentum", consists of multiple fragments of yellow/tan fibroadipose tissue (12 x 7 x 11 cm) which is grossly studded with tumor nodules ranging up to 4 cm in greatest dimension. The nodules are firm, white/tan with areas of necrosis. Representative sections are submitted for histologic evaluation.

Micro 33-34: 2 frags,

Part eleven, "spleen", consists of a 150 gm splenectomy specimen including a spleen (10.5 x 6.5 x 5 cm) and [] soft tissue (7 x 7 x 3 cm). The splenic soft tissue contains multiple white/tan nodules consistent with tumor measuring up to 1.5 cm in greatest dimension and focally infiltrating the splenic parenchyma. The splenic capsule contains focal areas of thickening consistent with [] tumor. The uninvolved splenic parenchyma is beefy red and unremarkable. No splenic lymph nodes are identified. Representative sections are submitted for histologic evaluation.

Micro 35: spleen with capsule of thickening, 1 frag,
Micro 36: tumor nodule infiltrating spleen, 1 frag,
Micro 37: tumor within [] splenic soft tissue, 2 frags,
Micro 38: tumor adjacent to spleen, 1 frag,

Part twelve, "tumor from mesentery transverse colon", consists of multiple

[page 4 of 4]
fragments of tan/pink soft tissue (3 x 3 x 2 cm). Representative sections are submitted for histologic evaluation.

Micro 39: 2 frags,

Part thirteen, "diaphragmatic tumor", consists of multiple fragments of white/tan soft tissue (10 x 9 x 2 cm in aggregate), which are grossly consistent with multiple tumor nodules. No identifiable skeletal muscle is present. Representative sections are submitted for histologic evaluation.

Micro 40: 2 frags,

Part fourteen, "sigmoid colon", consists of a single fragment of colon (6 cm in length by 2.5 cm in diameter) which is unoriented and has two opened resection margins. The mucosa is smooth and glistening with no evidence of masses or lesions. The serosa contains pericolic adipose tissue with no evidence of masses or lesions. No lymph nodes are identified. Representative sections are submitted for histologic evaluation.

Micro 41-42: margins of resection, en face, multiple frags,

Micro 43: representative cross section, 1 frag,

Part fifteen, "distal and proximal ends of anastomosis", consists of two colonic donuts (2 x 1.5 x 1 cm, 1 x 1 x 0.5 cm). Representative sections are submitted for histologic evaluation.

Micro 44: 4 frags,

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: TISSUE FOR SPECIAL STUDIES ONLY

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: LYMPH NODE BIOPSY

ADDITIONAL SPECIMEN TYPE: COLON, SEGMENTAL RESECTION OTHER THAN FOR TUMOR

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SPLEEN

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: COLON, SEGMENTAL RESECTION OTHER THAN FOR TUMOR

ADDITIONAL SPECIMEN TYPE: SURGICAL MARGIN

Source: NCI Genomic Data Commons file a87012ae-6a00-4896-9190-36c5f3d3449e (TCGA-30-1869.8D42D1A4-DFF9-47A9-B95B-2EB27747308C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).